Somatic mutation profile of tumor specimen TCGA-21-1082-01A (aliquot TCGA-21-1082-01A-01D-1521-08) from TCGA case TCGA-21-1082, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 61.6 years (22,492 days).
Specimen TCGA-21-1082-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e568e410-476d-455b-b020-8c008f34f0bc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-21-1082-10B (Blood Derived Normal), aliquot TCGA-21-1082-10B-01D-1521-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cea551fc-7f78-4c77-b668-2ac897c88b8a

The open-access MAF lists 423 somatic variants for this specimen: 309 protein-altering or splice-affecting, 101 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 258, Silent 101, Nonsense Mutation 27, Frame Shift Del 13, RNA 7, Splice Site 6, Splice Region 3, 5'Flank 3, Intron 2, Nonstop Mutation 1, 3'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1B | c.3184C>T p.R1062* | Nonsense Mutation (SNP) | VAF 37/108 reads (34%) | catalogued as rs387907144, CM122500, COSV51650129; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACSL6 | c.1340G>T p.R447L (on ENST00000379240; = p.R472L on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV57299727; called by muse, mutect2, varscan2
- ACTRT1 | c.597C>A p.S199R | Missense Mutation (SNP) | VAF 105/148 reads (71%) | SIFT tolerated (1); PolyPhen benign (0.096); catalogued as COSV100947537, COSV64420124; called by muse, mutect2, varscan2
- ADGRF4 | c.217G>C p.E73Q | Missense Mutation (SNP) | VAF 23/212 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.858); catalogued as COSV99348969; called by muse, mutect2, varscan2
- ADGRL3 | c.1558G>T p.G520* (on ENST00000506720 / NM_001322402.2; = p.G452* on NM_015236.6) | Nonsense Mutation (SNP) | VAF 68/148 reads (46%) | catalogued as COSV101547243; called by muse, mutect2, varscan2
- AL121899.2 | c.710G>T p.R237L | Missense Mutation (SNP) | VAF 118/215 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772095348, COSV67351818; called by muse, mutect2, varscan2
- ALDH5A1 | c.393G>A p.M131I | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated (0.47); PolyPhen benign (0.039); catalogued as COSV62374927; called by muse, mutect2, varscan2
- ANKRD35 | c.1573C>G p.P525A | Missense Mutation (SNP) | VAF 119/389 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV62910521; called by muse, mutect2, varscan2
- ANKS1A | c.1482G>T p.Q494H | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.556); catalogued as COSV64460944; called by muse, mutect2, varscan2
- APOB | c.11966G>A p.R3989H | Missense Mutation (SNP) | VAF 46/201 reads (23%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs148197354; ClinVar: uncertain significance; called by muse, varscan2
- ASXL3 | c.1258G>A p.A420T | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV99325602; called by muse, mutect2, varscan2
- ATG2A | c.5536G>A p.D1846N | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1259176806; called by muse, mutect2, varscan2
- ATP13A2 | c.2983G>A p.A995T | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as rs761512701; called by muse, mutect2, varscan2
- BCHE | c.1652C>T p.T551I | Missense Mutation (SNP) | VAF 44/220 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.144); catalogued as rs545173403; called by muse, mutect2, varscan2
- C10orf71 | c.676G>T p.E226* | Nonsense Mutation (SNP) | VAF 23/46 reads (50%) | catalogued as COSV100110366; called by muse, mutect2, varscan2
- CACNA1B | c.436G>T p.G146W | Missense Mutation (SNP) | VAF 51/135 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99055377; called by muse, mutect2, varscan2
- CACNA1B | c.437G>T p.G146V | Missense Mutation (SNP) | VAF 51/134 reads (38%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.927); catalogued as COSV53121174; called by muse, mutect2, varscan2
- CACNA1E | c.6512C>A p.S2171Y (on ENST00000367573 / NM_001205293.3; = p.S2128Y on NM_000721.4) | Missense Mutation (SNP) | VAF 71/233 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV62384483; called by muse, mutect2, varscan2
- CCT8L2 | c.485C>T p.S162F | Missense Mutation (SNP) | VAF 49/144 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.012); catalogued as COSV63463030; called by muse, mutect2, varscan2
- CD1B | c.133C>G p.Q45E | Missense Mutation (SNP) | VAF 235/675 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as rs775272128; called by muse, mutect2, varscan2
- CD300C | c.482C>G p.P161R | Missense Mutation (SNP) | VAF 6/150 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV100423284; called by muse, mutect2
- CENPE | c.913A>G p.I305V | Missense Mutation (SNP) | VAF 7/174 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs1289654646, COSV99478477; called by muse, mutect2
- CIB3 | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.201); catalogued as rs761552234; called by muse, mutect2, varscan2
- CLSTN2 | c.1858G>A p.E620K | Missense Mutation (SNP) | VAF 25/287 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.058); catalogued as rs762229815; called by muse, mutect2
- CSMD1 | c.2810G>T p.G937V (on ENST00000520002; = p.G936V on NM_033225.6) | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100152348, COSV59358374; called by muse, mutect2, varscan2
- CYP2C18 | c.332-1G>C p.X111_splice | Splice Site (SNP) | VAF 15/68 reads (22%) | catalogued as COSV99608703; called by muse, mutect2, varscan2
- CYP4F22 | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.082); catalogued as rs775752466; called by muse, mutect2, varscan2
- CYP4F8 | c.506A>T p.K169M | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as rs922556104, COSV100358166; called by muse, mutect2, varscan2
- CYRIA | c.916A>G p.T306A | Missense Mutation (SNP) | VAF 36/208 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV62866987; called by muse, mutect2, varscan2
- DGCR2 | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs776627102, COSV54216846, COSV99075874; called by muse, mutect2, varscan2
- DMBT1 | c.6231C>G p.I2077M (on ENST00000338354 / NM_001377530.1; = p.I1320M on NM_004406.3) | Missense Mutation (SNP) | VAF 87/155 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100353937; called by muse, mutect2, varscan2
- DNAH5 | c.5939G>A p.G1980E | Missense Mutation (SNP) | VAF 71/346 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1220504338; called by muse, mutect2, varscan2
- EIF2A | c.1100C>T p.P367L | Missense Mutation (SNP) | VAF 43/142 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs369784443; called by muse, mutect2, varscan2
- EPHA3 | c.834C>G p.Y278* | Nonsense Mutation (SNP) | VAF 82/197 reads (42%) | catalogued as COSV60707285, COSV60725198; called by muse, mutect2, varscan2
- FAM220A | c.377G>T p.G126V | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV100510826; called by muse, mutect2
- FAM47A | c.674del p.P225Rfs*41 | Frame Shift Del (DEL) | VAF 28/64 reads (44%) | catalogued as COSV60498580, COSV60499294; called by mutect2, pindel, varscan2
- FAM47A | c.99C>G p.C33W | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV60498649; called by muse, mutect2, varscan2
- FNDC1 | c.3856C>A p.P1286T | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.895); catalogued as rs1295580563; called by muse, mutect2
- GORASP2 | c.145-1G>A p.X49_splice | Splice Site (SNP) | VAF 42/89 reads (47%) | catalogued as COSV99304628; called by muse, mutect2, varscan2
- GPKOW | c.28C>T p.P10S | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs868990989; called by muse, mutect2, varscan2
- GRID2 | c.1420G>A p.V474I | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV56241063, COSV99943257; called by muse, mutect2
- GRPR | c.1086G>C p.K362N | Missense Mutation (SNP) | VAF 151/240 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as COSV66669905; called by muse, mutect2, varscan2
- GSDMB | c.181A>G p.I61V | Missense Mutation (SNP) | VAF 110/179 reads (61%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.63); catalogued as rs1411495460; called by muse, mutect2, varscan2
- HECTD1 | c.1903G>A p.E635K | Missense Mutation (SNP) | VAF 32/143 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.19); catalogued as COSV101237428; called by muse, mutect2, varscan2
- HORMAD1 | c.1021C>T p.Q341* | Nonsense Mutation (SNP) | VAF 6/33 reads (18%) | catalogued as COSV59271610; called by muse, varscan2
- HSD3B2 | c.746G>A p.R249Q | Missense Mutation (SNP) | VAF 21/159 reads (13%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as rs751984843, COSV65592990; called by muse, mutect2, varscan2
- IGHMBP2 | c.676G>C p.E226Q | Missense Mutation (SNP) | VAF 61/209 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as CM141742; called by muse, mutect2, varscan2
- IGKV2-24 | c.283G>T p.D95Y | Missense Mutation (SNP) | VAF 117/309 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs1352090689; called by muse, mutect2, varscan2
- KEL | c.1377G>A p.W459* | Nonsense Mutation (SNP) | VAF 30/68 reads (44%) | catalogued as rs61729052, CM022220; called by muse, mutect2, varscan2
- KRTAP21-2 | c.164C>T p.S55F | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as COSV100441147, COSV61684150; called by muse, mutect2, varscan2
- LCE1D | c.160G>C p.G54R | Missense Mutation (SNP) | VAF 34/118 reads (29%) | PolyPhen probably damaging (0.999); catalogued as COSV58271381; called by muse, mutect2, varscan2
- LHCGR | c.346C>A p.P116T | Missense Mutation (SNP) | VAF 75/224 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.085); catalogued as rs377265035; called by muse, mutect2, varscan2
- LMNTD2 | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.243); catalogued as rs759285014, COSV54238281; called by muse, mutect2, varscan2
- LRP1B | c.6503G>A p.C2168Y | Missense Mutation (SNP) | VAF 90/186 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67195334; called by muse, mutect2, varscan2
- LRRC36 | c.312G>C p.L104F | Missense Mutation (SNP) | VAF 22/218 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV52081718; called by muse, mutect2
- MAGEL2 | c.3385G>T p.E1129* | Nonsense Mutation (SNP) | VAF 21/69 reads (30%) | catalogued as COSV100046193, COSV99041371; called by muse, mutect2, varscan2
- MAPK8IP3 | c.1082G>T p.R361L | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.495); catalogued as rs751996288, COSV51718877, COSV51722167; called by muse, mutect2, varscan2
- MMP28 | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.36); catalogued as rs757698905; called by muse, mutect2
- MX2 | c.250-2A>T p.X84_splice | Splice Site (SNP) | VAF 35/133 reads (26%) | catalogued as COSV100416031; called by muse, mutect2, varscan2
- NFAT5 | c.1341C>G p.I447M | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63026102; called by muse, mutect2, varscan2
- NFIC | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 43/232 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs866417103, COSV59412951; called by muse, mutect2, varscan2
- NPC1 | c.833C>T p.A278V | Missense Mutation (SNP) | VAF 26/164 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs751947520; called by muse, mutect2, varscan2
- NPC1L1 | c.1016A>G p.Q339R | Missense Mutation (SNP) | VAF 68/218 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1214741307; called by muse, mutect2, varscan2
- NR3C2 | c.962C>T p.T321M | Missense Mutation (SNP) | VAF 53/96 reads (55%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.835); catalogued as rs776290874, COSV60996932; called by muse, mutect2, varscan2
- NUP210L | c.4303G>T p.D1435Y | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99668521; called by muse, mutect2, varscan2
- NUP210L | c.1070G>T p.G357V | Missense Mutation (SNP) | VAF 36/169 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV55150859; called by muse, mutect2, varscan2
- NWD1 | c.3818del p.G1273Afs*12 | Frame Shift Del (DEL) | VAF 58/195 reads (30%) | catalogued as COSV60352425; called by mutect2, pindel*, varscan2
- OCA2 | c.1662G>T p.W554C | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62339015; called by muse, mutect2, varscan2
- OCLN | c.208A>G p.M70V | Missense Mutation (SNP) | VAF 158/294 reads (54%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs778368708, COSV62284981; called by muse, mutect2, varscan2
- OGDHL | c.2590+1G>T p.X864_splice | Splice Site (SNP) | VAF 21/53 reads (40%) | catalogued as COSV100934406; called by muse, mutect2, varscan2
- OR1S2 | c.563C>T p.P188L | Missense Mutation (SNP) | VAF 78/266 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.805); catalogued as COSV100224273; called by muse, mutect2, varscan2
- OR4L1 | c.817G>T p.V273L | Missense Mutation (SNP) | VAF 78/218 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.597); catalogued as COSV59849785; called by muse, mutect2, varscan2
- OR8B8 | c.206T>C p.I69T | Missense Mutation (SNP) | VAF 57/140 reads (41%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.721); catalogued as rs767201422; called by muse, mutect2, varscan2
- PAH | c.733G>T p.V245L | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as CM961077; called by muse, mutect2, varscan2
- PCDHA4 | c.744G>C p.K248N | Missense Mutation (SNP) | VAF 58/111 reads (52%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.063); catalogued as COSV63546224; called by muse, mutect2, varscan2
- PCDHB11 | c.1691C>T p.P564L | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as COSV100697081; called by muse, mutect2, varscan2
- PLCH1 | c.1855G>T p.D619Y (on ENST00000340059 / NM_001130960.2; = p.D631Y on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 72/394 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58204127; called by muse, mutect2, varscan2
- PLEKHO2 | c.1345G>C p.E449Q | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV60262018; called by muse, mutect2, varscan2
- POM121L12 | c.567C>A p.S189R | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT tolerated (0.89); PolyPhen benign (0.422); catalogued as COSV68694200; called by muse, mutect2, varscan2
- POP1 | c.2339C>T p.S780L | Missense Mutation (SNP) | VAF 128/322 reads (40%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as rs149744031; called by muse, varscan2
- PPP4R1 | c.1234del p.S412Qfs*37 (on ENST00000400556 / NM_001042388.3; = p.S395Qfs*37 on NM_005134.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 88/227 reads (39%) | catalogued as COSV53280543; called by mutect2, pindel*, varscan2*
- PRAME | c.169T>G p.F57V | Missense Mutation (SNP) | VAF 80/304 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769323726; called by muse, mutect2, varscan2
- PTPRC | c.305C>T p.S102L | Missense Mutation (SNP) | VAF 109/288 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV100722422; called by muse, mutect2, varscan2
- RBM12 | c.1735G>C p.D579H | Missense Mutation (SNP) | VAF 24/774 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100467748; called by muse, mutect2
- RFX6 | c.2053A>G p.I685V | Missense Mutation (SNP) | VAF 98/310 reads (32%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs369719975; called by muse, mutect2, varscan2
- RIMS1 | c.1889G>T p.R630L | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53474518; called by muse, mutect2, varscan2
- RNF32 | c.814G>C p.E272Q | Missense Mutation (SNP) | VAF 61/117 reads (52%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as COSV58733452; called by muse, mutect2, varscan2
- RTBDN | c.475G>C p.G159R (on ENST00000393233 / NM_001270444.1; = p.G191R on NM_031429.2) | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs537117488, COSV100530726; called by muse, mutect2, varscan2
- RYR2 | c.7993G>T p.A2665S | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.505); catalogued as COSV100771999, COSV63672383, COSV63688685; called by muse, mutect2, varscan2
- RYR3 | c.2508T>A p.D836E | Missense Mutation (SNP) | VAF 110/349 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.085); catalogued as COSV66807412; called by muse, mutect2, varscan2
- S100A7 | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 70/189 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as rs777094796; called by muse, mutect2, varscan2
- SFRP4 | c.23C>A p.A8E | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.17); catalogued as rs572680887; called by muse, mutect2, varscan2
- SGK2 | c.20C>A p.S7* | Nonsense Mutation (SNP) | VAF 140/248 reads (56%) | catalogued as COSV58315018; called by muse, mutect2, varscan2
- SHANK1 | c.949G>T p.E317* | Nonsense Mutation (SNP) | VAF 90/228 reads (39%) | catalogued as COSV53256140; called by muse, mutect2, varscan2
- SIGLEC5 | c.1069G>T p.A357S | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.873); catalogued as rs1397495214; called by muse, varscan2
- SLC13A1 | c.534C>A p.N178K | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.886); catalogued as rs1251828107, COSV52018527; called by muse, mutect2, varscan2
- SLC4A7 | c.2335C>G p.L779V | Missense Mutation (SNP) | VAF 10/264 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as rs1411144285, COSV55395125; called by muse, mutect2
- SLC9A2 | c.2068+1G>T p.X690_splice | Splice Site (SNP) | VAF 15/32 reads (47%) | catalogued as COSV99296477; called by muse, mutect2, varscan2
- SLCO1B1 | c.280C>A p.P94T | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778697943, COSV57012833; called by muse, mutect2, varscan2
- SLCO2A1 | c.547G>A p.G183R | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774038272, CM1312618, COSV100189501; called by muse, mutect2, varscan2
- SNTG1 | c.1091C>A p.S364Y | Missense Mutation (SNP) | VAF 68/236 reads (29%) | SIFT tolerated (0.98); PolyPhen benign (0.188); catalogued as COSV52475315; called by muse, mutect2, varscan2
- SOGA1 | c.898G>C p.E300Q | Missense Mutation (SNP) | VAF 95/206 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs968990795; called by muse, mutect2, varscan2
- SPRY3 | c.785G>T p.C262F | Missense Mutation (SNP) | VAF 116/199 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV57143273; called by muse, mutect2, varscan2
- TBCC | c.88C>T p.Q30* | Nonsense Mutation (SNP) | VAF 44/146 reads (30%) | catalogued as rs752952851; called by mutect2, varscan2
- TCF25 | c.232G>C p.G78R | Missense Mutation (SNP) | VAF 75/201 reads (37%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.77); catalogued as COSV54529926; called by muse, mutect2, varscan2
- TGM6 | c.621C>G p.D207E | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.583); catalogued as rs148696208; called by muse, mutect2, varscan2
- TGS1 | c.1975G>C p.D659H | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52703627, COSV99485395; called by muse, mutect2, varscan2
- TMEM131L | c.820G>C p.E274Q | Missense Mutation (SNP) | VAF 50/118 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.869); catalogued as COSV99548373; called by muse, mutect2, varscan2
- TPR | c.4904C>T p.S1635F | Missense Mutation (SNP) | VAF 22/288 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.045); catalogued as COSV100824075; called by muse, mutect2
- TRIML2 | c.621G>T p.K207N | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.358); catalogued as COSV58714688; called by muse, mutect2, varscan2
- UBE3C | c.2234-1G>C p.X745_splice | Splice Site (SNP) | VAF 7/178 reads (4%) | catalogued as COSV100780015; called by muse, mutect2
- UBE4A | c.256C>T p.H86Y | Missense Mutation (SNP) | VAF 17/607 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.188); catalogued as COSV99348367; called by muse, mutect2
- UGT1A4 | c.865C>G p.Q289E | Missense Mutation (SNP) | VAF 89/244 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.305); catalogued as COSV100530486; called by muse, mutect2, varscan2
- ZBBX | c.86G>A p.R29Q | Missense Mutation (SNP) | VAF 58/294 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0.022); catalogued as rs760372262, COSV56794402; called by muse, mutect2, varscan2
- ZC3H12C | c.2009G>T p.R670L | Missense Mutation (SNP) | VAF 132/428 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.088); catalogued as COSV99584558; called by muse, mutect2, varscan2
- ZFYVE16 | c.2933C>T p.P978L | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as COSV100566514; called by muse, mutect2
- ZG16B | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.114); catalogued as COSV66525881; called by muse, mutect2, varscan2
- ZMYND10 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs587731307; called by muse, mutect2
- ZNF107 | c.1207A>G p.R403G | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs575000457; called by muse, mutect2, varscan2
- ZNF20 | c.829C>T p.H277Y | Missense Mutation (SNP) | VAF 50/160 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100503029; called by muse, mutect2, varscan2
- ZNF205 | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 46/157 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.142); catalogued as rs775487028, COSV54622134; called by muse, mutect2, varscan2
- ZNF33A | c.2303_2304del p.R768Kfs*10 (on ENST00000458705 / NM_006974.3; = p.R769Kfs*10 on NM_006954.2) | Frame Shift Del (DEL) | VAF 35/172 reads (20%) | catalogued as COSV56726361; called by pindel, varscan2
- ZNF516 | c.2641G>T p.G881C | Missense Mutation (SNP) | VAF 75/201 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV101487269; called by muse, mutect2, varscan2
- ZNF585B | c.1562C>A p.P521H | Missense Mutation (SNP) | VAF 10/230 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100459544; called by muse, mutect2
- ZNF696 | c.769C>T p.R257W | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs530763271, COSV57524891; called by muse, mutect2, varscan2
- ZNF709 | c.688G>A p.G230R | Missense Mutation (SNP) | VAF 80/225 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs752544330; called by muse, mutect2, varscan2
- AASS | c.281G>C p.R94T | Missense Mutation (SNP) | VAF 71/125 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- ABCC12 | c.249T>A p.Y83* | Nonsense Mutation (SNP) | VAF 51/172 reads (30%) | called by muse, mutect2, varscan2
- ACVR1 | c.427G>T p.G143* | Nonsense Mutation (SNP) | VAF 38/70 reads (54%) | called by muse, mutect2, varscan2
- ADAD1 | c.27G>T p.Q9H | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- ADAM18 | c.1583C>A p.S528Y | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- ADAMTS2 | c.690G>T p.G230= | Splice Region (SNP) | VAF 50/146 reads (34%) | called by muse, mutect2, varscan2
- ADAMTS20 | c.3633G>T p.W1211C | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ADAMTS20 | c.3632G>T p.W1211L | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ADIPOR1 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ALS2CL | c.2144A>T p.E715V | Missense Mutation (SNP) | VAF 101/172 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- ANK1 | c.5305G>C p.E1769Q | Missense Mutation (SNP) | VAF 63/225 reads (28%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- ANK2 | c.5113A>G p.R1705G | Missense Mutation (SNP) | VAF 81/158 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- ANKRD35 | c.391G>T p.G131C | Missense Mutation (SNP) | VAF 60/183 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- APLNR | c.139G>T p.G47C | Missense Mutation (SNP) | VAF 82/223 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARHGAP18 | c.638G>T p.G213V | Missense Mutation (SNP) | VAF 86/286 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARHGAP29 | c.1088del p.N363Ifs*6 | Frame Shift Del (DEL) | VAF 68/273 reads (25%) | called by pindel, varscan2
- ARHGAP29 | c.1082C>T p.A361V | Missense Mutation (SNP) | VAF 76/239 reads (32%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, varscan2
- ARHGAP33 | c.887G>T p.R296L | Missense Mutation (SNP) | VAF 41/151 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- ARHGAP36 | c.486C>G p.I162M | Missense Mutation (SNP) | VAF 76/100 reads (76%) | SIFT tolerated (0.26); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ARHGAP36 | c.1402G>T p.E468* | Nonsense Mutation (SNP) | VAF 75/117 reads (64%) | called by muse, mutect2, varscan2
- ATP13A3 | c.39A>C p.Q13H | Missense Mutation (SNP) | VAF 31/204 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ATP2C2 | c.1192G>C p.D398H | Missense Mutation (SNP) | VAF 144/395 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AWAT1 | c.856C>T p.Q286* | Nonsense Mutation (SNP) | VAF 24/35 reads (69%) | called by muse, mutect2, varscan2
- BCL9L | c.2981G>T p.R994M | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- BCL9L | c.97G>T p.A33S | Missense Mutation (SNP) | VAF 56/142 reads (39%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- C11orf16 | c.1356G>T p.K452N | Missense Mutation (SNP) | VAF 101/217 reads (47%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- C8orf34 | c.335del p.M112Rfs*4 | Frame Shift Del (DEL) | VAF 31/108 reads (29%) | called by mutect2, pindel
- CARS2 | c.1411C>A p.Q471K | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CASP14 | c.273G>T p.R91S | Missense Mutation (SNP) | VAF 51/205 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- CBLL1 | c.175G>C p.D59H | Missense Mutation (SNP) | VAF 56/87 reads (64%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- CCNB3 | c.1177G>A p.G393R | Missense Mutation (SNP) | VAF 48/75 reads (64%) | SIFT tolerated (0.45); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CD93 | c.1217C>T p.S406L | Missense Mutation (SNP) | VAF 98/180 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CDYL | c.1630A>T p.N544Y (on ENST00000328908 / NM_001368125.1; = p.N490Y on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/155 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- CEP250 | c.7156G>T p.G2386C | Missense Mutation (SNP) | VAF 90/169 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- CEP290 | c.3677C>G p.S1226C | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- CFAP299 | c.125C>A p.A42D | Missense Mutation (SNP) | VAF 109/233 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- CLMP | c.977C>T p.P326L | Missense Mutation (SNP) | VAF 75/237 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- CLN3 | c.1020G>T p.W340C (on ENST00000360019 / NM_001286104.2; = p.W364C on NM_000086.2) | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CMYA5 | c.6484G>T p.A2162S | Missense Mutation (SNP) | VAF 46/96 reads (48%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- COL6A2 | c.1480G>T p.D494Y | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- COL6A3 | c.6575G>T p.G2192V | Missense Mutation (SNP) | VAF 234/592 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COLEC12 | c.1701G>T p.L567F | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- CREBBP | c.6129G>T p.Q2043H | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- CSMD1 | c.7950C>A p.N2650K (on ENST00000520002; = p.N2649K on NM_033225.6) | Missense Mutation (SNP) | VAF 160/452 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- CTH | c.889C>T p.H297Y | Missense Mutation (SNP) | VAF 7/148 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CTNNA2 | c.2606C>A p.A869D (on ENST00000402739 / NM_001282597.3; = p.A821D on NM_004389.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 73/223 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CUX2 | c.2261C>A p.P754H | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- CYP4V2 | c.615G>T p.M205I | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CYSLTR2 | c.267C>A p.S89R | Missense Mutation (SNP) | VAF 49/106 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- DAND5 | c.347C>G p.S116* | Nonsense Mutation (SNP) | VAF 52/171 reads (30%) | called by muse, mutect2, varscan2
- DDX25 | c.1429G>A p.E477K | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- DNAJC19 | c.244C>G p.H82D | Missense Mutation (SNP) | VAF 16/226 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DRG1 | c.903G>T p.Q301H | Missense Mutation (SNP) | VAF 114/396 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- DSCAM | c.5176C>A p.P1726T | Missense Mutation (SNP) | VAF 72/246 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- DSG4 | c.323A>T p.E108V | Missense Mutation (SNP) | VAF 55/139 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- DUSP16 | c.1646C>G p.S549C | Missense Mutation (SNP) | VAF 13/336 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.781); called by muse, mutect2
- DYRK4 | c.553C>T p.L185F | Missense Mutation (SNP) | VAF 53/168 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- EBF2 | c.661G>T p.D221Y | Missense Mutation (SNP) | VAF 7/166 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); called by muse, mutect2
- EGFLAM | c.2947G>A p.G983R (on ENST00000354891 / NM_001205301.2; = p.G975R on NM_152403.4) | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPHA5 | c.682G>T p.V228L | Missense Mutation (SNP) | VAF 61/109 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FAM83G | c.1735G>T p.V579L | Missense Mutation (SNP) | VAF 79/151 reads (52%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GLP2R | c.1507C>A p.L503I | Missense Mutation (SNP) | VAF 79/128 reads (62%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GPATCH2 | c.457G>T p.V153F | Missense Mutation (SNP) | VAF 93/180 reads (52%) | SIFT tolerated (0.69); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- H4C3 | c.30_40del p.L11Wfs*3 | Frame Shift Del (DEL) | VAF 31/164 reads (19%) | called by mutect2, pindel, varscan2
- HAUS1 | c.278G>T p.R93M | Missense Mutation (SNP) | VAF 81/257 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- HCN3 | c.2155C>G p.L719V | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- HINFP | c.913A>G p.T305A | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- HORMAD1 | c.946C>G p.Q316E | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.113); called by muse, mutect2
- HPSE2 | c.84C>A p.Y28* | Nonsense Mutation (SNP) | VAF 66/131 reads (50%) | called by muse, mutect2, varscan2
- IGKV1D-8 | c.205C>A p.L69M | Missense Mutation (SNP) | VAF 89/277 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- IGLV10-54 | c.224C>A p.P75H | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- IKBIP | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- INMT | c.68C>T p.T23I | Missense Mutation (SNP) | VAF 88/311 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- KANK4 | c.127G>A p.V43M | Missense Mutation (SNP) | VAF 100/287 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNC2 | c.545A>C p.D182A | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2
- KCNH1 | c.1501A>G p.I501V (on ENST00000271751 / NM_172362.3; = p.I474V on NM_002238.4) | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- KHNYN | c.1523C>A p.S508Y | Missense Mutation (SNP) | VAF 91/293 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KHSRP | c.1009del p.V337Sfs*8 | Frame Shift Del (DEL) | VAF 10/84 reads (12%) | called by mutect2, pindel, varscan2
- KLHL30 | c.1670G>T p.G557V | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- KNL1 | c.933G>T p.Q311H (on ENST00000346991 / NM_170589.5; = p.Q285H on NM_144508.5) | Missense Mutation (SNP) | VAF 55/145 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- LHCGR | c.1545C>A p.F515L | Missense Mutation (SNP) | VAF 53/194 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- LILRB5 | c.1313C>A p.P438H (on ENST00000449561 / NM_001081442.3; = p.P437H on NM_006840.5) | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- LNP1 | c.325G>C p.E109Q | Missense Mutation (SNP) | VAF 59/168 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRIG3 | c.2683C>G p.H895D | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT tolerated (0.6); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- LRP1B | c.8327C>A p.P2776H | Missense Mutation (SNP) | VAF 97/190 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- LRP1B | c.1696_1702del p.E566Ifs*12 | Frame Shift Del (DEL) | VAF 118/238 reads (50%) | called by mutect2, pindel, varscan2
- LRRK1 | c.6016C>G p.R2006G | Missense Mutation (SNP) | VAF 35/144 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- MACF1 | c.20971G>A p.A6991T (on ENST00000372915; = p.A5036T on NM_012090.5) | Missense Mutation (SNP) | VAF 38/150 reads (25%) | called by muse, mutect2, varscan2
- MAPK8IP3 | c.1452A>G p.K484= | Splice Region (SNP) | VAF 7/112 reads (6%) | called by muse, mutect2
- MARF1 | c.2611del p.A871Lfs*9 | Frame Shift Del (DEL) | VAF 29/142 reads (20%) | called by mutect2, pindel, varscan2
- MGAT4A | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 49/149 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- MIXL1 | c.563A>T p.N188I | Missense Mutation (SNP) | VAF 61/125 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- MRPL47 | c.245G>C p.G82A | Missense Mutation (SNP) | VAF 43/259 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MRPS35 | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYOM3 | c.2698C>A p.P900T | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.382); called by mutect2, varscan2
- MYOT | c.1489G>A p.E497K | Missense Mutation (SNP) | VAF 45/86 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NAV3 | c.5638C>G p.Q1880E (on ENST00000397909 / NM_001024383.2; = p.Q1858E on NM_014903.6) | Missense Mutation (SNP) | VAF 48/159 reads (30%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- NEK3 | c.152C>G p.A51G | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); called by muse, mutect2
- NOP53 | c.1407G>C p.E469D | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- NOS2 | c.494G>T p.R165M | Missense Mutation (SNP) | VAF 61/129 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- NPAT | c.118C>T p.H40Y | Missense Mutation (SNP) | VAF 49/181 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NPTXR | c.1247C>T p.P416L | Missense Mutation (SNP) | VAF 53/204 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NUP210L | c.1069G>T p.G357* | Nonsense Mutation (SNP) | VAF 37/172 reads (22%) | called by muse, mutect2, varscan2
- OR10Q1 | c.266T>C p.I89T | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- OR2G3 | c.160C>A p.P54T | Missense Mutation (SNP) | VAF 183/405 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- OR4K1 | c.300G>T p.Q100H | Missense Mutation (SNP) | VAF 96/256 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- OSGIN2 | c.16G>C p.E6Q | Missense Mutation (SNP) | VAF 9/135 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.543); called by muse, mutect2
- PANX3 | c.709C>G p.Q237E | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- PAPPA2 | c.2491G>T p.D831Y | Missense Mutation (SNP) | VAF 128/372 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PHF20 | c.884A>T p.E295V | Missense Mutation (SNP) | VAF 59/289 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- PLCH1 | c.155G>T p.R52L (on ENST00000340059 / NM_001130960.2; = p.R64L on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 340/678 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); called by muse, mutect2
- PLOD2 | c.220G>C p.E74Q | Missense Mutation (SNP) | VAF 51/316 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- POLR2A | c.2233C>G p.L745V | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- POTEA | c.193G>C p.D65H | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- PPIL6 | c.451G>C p.D151H | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- PRKDC | c.5830G>T p.A1944S | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PRKN | c.166G>T p.V56L | Missense Mutation (SNP) | VAF 41/152 reads (27%) | SIFT tolerated (0.81); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PRMT5 | c.453C>T p.F151= | Splice Region (SNP) | VAF 36/237 reads (15%) | called by muse, mutect2, varscan2
- PSMD8 | c.44G>A p.R15Q | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); called by muse, varscan2
- PSME4 | c.1218G>T p.L406F | Missense Mutation (SNP) | VAF 43/125 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.595); called by muse, mutect2, varscan2
- R3HDM1 | c.1366G>C p.D456H | Missense Mutation (SNP) | VAF 27/252 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); called by muse, mutect2
- RANBP2 | c.4381C>T p.Q1461* | Nonsense Mutation (SNP) | VAF 30/130 reads (23%) | called by muse, mutect2, varscan2
- RERG | c.595A>G p.S199G | Missense Mutation (SNP) | VAF 129/358 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- RET | c.2749T>C p.W917R | Missense Mutation (SNP) | VAF 106/205 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RIMBP2 | c.1642G>T p.A548S | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.1); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- RIOX2 | c.1153G>A p.E385K (on ENST00000333396 / NM_001042533.2; = p.E384K on NM_032778.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- RO60 | c.587C>G p.A196G | Missense Mutation (SNP) | VAF 46/171 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- RTL3 | c.577G>C p.E193Q | Missense Mutation (SNP) | VAF 62/103 reads (60%) | SIFT tolerated (0.06); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- S1PR5 | c.1148G>T p.G383V | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- SACS | c.5163del p.A1723Hfs*2 | Frame Shift Del (DEL) | VAF 43/99 reads (43%) | called by mutect2, pindel, varscan2
- SCLY | c.844G>T p.G282C (on ENST00000651534; = p.G274C on NM_016510.7) | Missense Mutation (SNP) | VAF 30/196 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SDHA | c.679G>C p.E227Q | Missense Mutation (SNP) | VAF 16/197 reads (8%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.113); called by muse, mutect2
- SEMA6B | c.766G>C p.E256Q | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.704); called by muse, mutect2
- SF3A1 | c.827G>A p.W276* | Nonsense Mutation (SNP) | VAF 64/144 reads (44%) | called by muse, mutect2, varscan2
- SF3B2 | c.1927C>A p.P643T | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SHANK1 | c.948G>T p.Q316H | Missense Mutation (SNP) | VAF 88/228 reads (39%) | SIFT tolerated (0.43); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- SIGLEC1 | c.3560A>T p.Q1187L | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.532); called by muse, mutect2, varscan2
- SLC28A1 | c.587C>G p.S196* | Nonsense Mutation (SNP) | VAF 33/292 reads (11%) | called by muse, mutect2, varscan2
- SLC5A5 | c.778G>T p.G260C | Missense Mutation (SNP) | VAF 52/182 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- SLF1 | c.2502C>G p.I834M | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLIT2 | c.2771C>G p.S924* | Nonsense Mutation (SNP) | VAF 112/217 reads (52%) | called by muse, mutect2, varscan2
- SMG6 | c.1480G>C p.A494P | Missense Mutation (SNP) | VAF 307/457 reads (67%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- SOHLH1 | c.476A>T p.D159V | Missense Mutation (SNP) | VAF 38/70 reads (54%) | SIFT tolerated (0.18); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- SPEF2 | c.3478A>C p.N1160H | Missense Mutation (SNP) | VAF 40/486 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); called by muse, mutect2
- SPRY2 | c.939del p.K313Nfs*42 | Frame Shift Del (DEL) | VAF 13/60 reads (22%) | called by mutect2, pindel, varscan2
- STAB1 | c.6578C>G p.S2193* | Nonsense Mutation (SNP) | VAF 22/185 reads (12%) | called by muse, mutect2, varscan2
- STYXL2 | c.1774T>A p.W592R | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- STYXL2 | c.1807G>C p.E603Q | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- SUCO | c.1072C>T p.P358S | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SUGP1 | c.1021G>T p.E341* | Nonsense Mutation (SNP) | VAF 59/161 reads (37%) | called by muse, mutect2, varscan2
- SUN5 | c.526T>A p.S176T | Missense Mutation (SNP) | VAF 22/546 reads (4%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.98); called by muse, mutect2
- TAAR1 | c.662C>A p.A221E | Missense Mutation (SNP) | VAF 56/178 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- TAAR5 | c.632C>A p.P211H | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TAS2R41 | c.667G>T p.D223Y | Missense Mutation (SNP) | VAF 62/110 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- TAS2R43 | c.105G>T p.W35C | Missense Mutation (SNP) | VAF 43/152 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.399); called by muse, mutect2, varscan2
- TBCC | c.1006C>G p.L336V | Missense Mutation (SNP) | VAF 41/133 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- TBL1Y | c.1081G>C p.E361Q | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- TEAD3 | c.1285G>C p.V429L | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.569); called by muse, mutect2
- TMEM52 | c.271C>G p.L91V | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- TMX4 | c.868G>T p.D290Y | Missense Mutation (SNP) | VAF 129/279 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- TNFRSF11B | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 102/347 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TNIK | c.2962G>C p.D988H | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- TNR | c.714C>A p.D238E | Missense Mutation (SNP) | VAF 78/234 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TOX2 | c.657G>T p.E219D (on ENST00000358131 / NM_001098798.2; = p.E168D on NM_032883.3) | Missense Mutation (SNP) | VAF 59/108 reads (55%) | SIFT tolerated (0.64); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- TOX2 | c.658G>T p.E220* (on ENST00000358131 / NM_001098798.2; = p.E169* on NM_032883.3) | Nonsense Mutation (SNP) | VAF 59/108 reads (55%) | called by muse, mutect2, varscan2
- TP53 | c.575_580del p.Q192_H193del | In Frame Del (DEL) | VAF 36/70 reads (51%) | called by mutect2, pindel, varscan2
- TPPP2 | c.224A>G p.K75R | Missense Mutation (SNP) | VAF 64/170 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, varscan2
- TRABD2A | c.1156G>T p.V386L (on ENST00000409520 / NM_001277053.2; = p.V337L on NM_001080824.3) | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- UBN1 | c.2765G>T p.G922V | Missense Mutation (SNP) | VAF 24/157 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- UBR2 | c.4759G>T p.E1587* | Nonsense Mutation (SNP) | VAF 45/157 reads (29%) | called by muse, mutect2, varscan2
- USP33 | c.806A>C p.Q269P | Missense Mutation (SNP) | VAF 36/169 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VPS13C | c.10775C>G p.S3592C (on ENST00000644861 / NM_020821.3; = p.S3549C on NM_017684.5) | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- WBP1 | c.385G>T p.D129Y | Missense Mutation (SNP) | VAF 70/273 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- XAB2 | c.56A>C p.E19A | Missense Mutation (SNP) | VAF 57/114 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- XPOT | c.2584C>G p.P862A | Missense Mutation (SNP) | VAF 55/155 reads (35%) | SIFT tolerated (0.96); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZAP70 | c.1104C>G p.I368M | Missense Mutation (SNP) | VAF 53/147 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- ZBBX | c.1066C>G p.Q356E | Missense Mutation (SNP) | VAF 42/370 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- ZHX2 | c.2514G>C p.*838Yext*18 | Nonstop Mutation (SNP) | VAF 13/56 reads (23%) | called by muse, mutect2, varscan2
- ZNF200 | c.493G>T p.E165* | Nonsense Mutation (SNP) | VAF 39/126 reads (31%) | called by muse, mutect2, varscan2
- ZNF786 | c.2300del p.K767Rfs*10 | Frame Shift Del (DEL) | VAF 207/462 reads (45%) | called by mutect2, pindel, varscan2
- ZNF80 | c.623G>T p.S208I | Missense Mutation (SNP) | VAF 70/192 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- ZPR1 | c.1135G>T p.G379* | Nonsense Mutation (SNP) | VAF 33/131 reads (25%) | called by muse, mutect2, varscan2
- ZSCAN20 | c.44C>A p.P15Q | Missense Mutation (SNP) | VAF 64/188 reads (34%) | SIFT tolerated (0.63); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ACAP2 | c.1494G>A p.E498= | Silent (SNP) | VAF 15/154 reads (10%) | called by muse, mutect2, varscan2
- ACTRT2 | c.186C>T p.A62= | Silent (SNP) | VAF 55/142 reads (39%) | catalogued as rs756159916, COSV101007638; called by muse, mutect2, varscan2
- ALG10B | c.1287A>C p.I429= | Silent (SNP) | VAF 17/399 reads (4%) | catalogued as COSV100439937; called by muse, mutect2
- ARMC1 | c.75A>G p.A25= | Silent (SNP) | VAF 82/260 reads (32%) | called by muse, mutect2, varscan2
- ARSG | c.621C>G p.L207= | Silent (SNP) | VAF 47/104 reads (45%) | catalogued as COSV101477873, COSV71593698; called by muse, mutect2, varscan2
- ASB9 | c.39C>G p.P13= | Silent (SNP) | VAF 67/108 reads (62%) | catalogued as COSV66852309; called by muse, mutect2, varscan2
- AWAT1 | c.855C>A p.P285= | Silent (SNP) | VAF 24/35 reads (69%) | called by muse, mutect2, varscan2
- BARX1 | c.723G>A p.A241= | Silent (SNP) | VAF 16/37 reads (43%) | called by muse, mutect2, varscan2
- C9orf43 | c.609A>G p.L203= | Silent (SNP) | VAF 37/75 reads (49%) | called by muse, mutect2, varscan2
- CAPRIN2 | c.2517A>G p.R839= | Silent (SNP) | VAF 8/185 reads (4%) | catalogued as COSV99195548; called by muse, mutect2
- CAV1 | c.453C>T p.Y151= | Silent (SNP) | VAF 54/112 reads (48%) | catalogued as rs750447403; ClinVar: likely benign; called by muse, mutect2, varscan2
- CCDC60 | c.48G>T p.S16= | Silent (SNP) | VAF 60/160 reads (38%) | called by muse, mutect2, varscan2
- CD320 | c.771G>A p.E257= | Silent (SNP) | VAF 119/192 reads (62%) | called by muse, mutect2, varscan2
- CFHR4 | c.45T>C p.C15= | Silent (SNP) | VAF 82/216 reads (38%) | called by muse, mutect2, varscan2
- CHST8 | c.348C>A p.I116= | Silent (SNP) | VAF 12/40 reads (30%) | called by muse, varscan2
- COL4A4 | c.3765T>A p.P1255= | Silent (SNP) | VAF 20/62 reads (32%) | called by muse, mutect2, varscan2
- CRYZL1 | c.855G>C p.L285= | Silent (SNP) | VAF 21/208 reads (10%) | called by muse, mutect2, varscan2
- CSMD1 | c.6507C>A p.I2169= (on ENST00000520002; = p.I2168= on NM_033225.6) | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as COSV59357293; called by muse, mutect2, varscan2
- CYP2E1 | c.1011A>G p.R337= | Silent (SNP) | VAF 44/92 reads (48%) | called by muse, mutect2, varscan2
- DCLK1 | c.99G>A p.P33= | Silent (SNP) | VAF 66/125 reads (53%) | catalogued as rs754667282; called by muse, mutect2, varscan2
- DCT | c.456A>G p.V152= | Silent (SNP) | VAF 176/597 reads (29%) | called by muse, mutect2, varscan2
- DDX27 | c.1017G>T p.A339= | Silent (SNP) | VAF 18/136 reads (13%) | called by muse, mutect2, varscan2
- DMRT3 | c.1053C>A p.P351= | Silent (SNP) | VAF 45/91 reads (49%) | catalogued as COSV51908447; called by muse, mutect2, varscan2
- DNAH5 | c.10899C>T p.F3633= | Silent (SNP) | VAF 10/280 reads (4%) | called by muse, mutect2
- DNAJC28 | c.798T>A p.T266= | Silent (SNP) | VAF 174/509 reads (34%) | called by muse, mutect2, varscan2
- DUOX1 | c.2199G>A p.L733= | Silent (SNP) | VAF 98/274 reads (36%) | called by muse, mutect2, varscan2
- ESPL1 | c.2151G>A p.L717= | Silent (SNP) | VAF 6/148 reads (4%) | called by muse, mutect2
- FAM167A | c.249C>A p.L83= | Silent (SNP) | VAF 28/94 reads (30%) | catalogued as COSV99461409; called by muse, mutect2, varscan2
- FOXM1 | c.261C>T p.I87= | Silent (SNP) | VAF 67/178 reads (38%) | catalogued as rs11548398, COSV100700929; called by muse, mutect2, varscan2
- FSIP1 | c.1674C>G p.L558= | Silent (SNP) | VAF 68/215 reads (32%) | called by muse, mutect2, varscan2
- G6PC | c.585C>T p.F195= | Silent (SNP) | VAF 29/112 reads (26%) | catalogued as COSV53832384; called by muse, mutect2, varscan2
- GDF2 | c.27C>A p.A9= | Silent (SNP) | VAF 6/13 reads (46%) | called by muse, mutect2, varscan2
- HERC2 | c.1131C>A p.L377= | Silent (SNP) | VAF 7/93 reads (8%) | catalogued as COSV99875143; called by muse, mutect2
- HLTF | c.366C>T p.I122= | Silent (SNP) | VAF 25/332 reads (8%) | catalogued as rs753530650, COSV100026945; called by muse, mutect2
- HMGN3 | c.90G>A p.L30= | Silent (SNP) | VAF 135/440 reads (31%) | called by muse, mutect2, varscan2
- HTR3C | c.1167A>C p.A389= | Silent (SNP) | VAF 42/158 reads (27%) | called by muse, varscan2
- IFT52 | c.1056G>A p.E352= | Silent (SNP) | VAF 104/213 reads (49%) | called by muse, mutect2, varscan2
- IHH | c.918G>T p.V306= | Silent (SNP) | VAF 20/37 reads (54%) | called by muse, mutect2, varscan2
- IMMT | c.2067A>G p.K689= | Silent (SNP) | VAF 7/145 reads (5%) | catalogued as COSV99606458; called by muse, mutect2
- INF2 | c.759C>T p.A253= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as rs1390597939; called by muse, mutect2, varscan2
- IRX2 | c.747G>T p.L249= | Silent (SNP) | VAF 55/94 reads (59%) | called by muse, mutect2, varscan2
- ITGA10 | c.720A>C p.G240= | Silent (SNP) | VAF 39/99 reads (39%) | called by muse, mutect2, varscan2
- KMT2B | c.6423C>T p.P2141= | Silent (SNP) | VAF 5/12 reads (42%) | called by muse, varscan2
- KRT82 | c.915C>A p.A305= | Silent (SNP) | VAF 69/218 reads (32%) | called by muse, mutect2, varscan2
- LHCGR | c.1515C>A p.V505= | Silent (SNP) | VAF 54/187 reads (29%) | catalogued as COSV54301872; called by muse, varscan2
- LRRC27 | c.720G>T p.L240= | Silent (SNP) | VAF 39/69 reads (57%) | called by muse, mutect2, varscan2
- MAP2K3 | c.760C>T p.L254= (on ENST00000342679 / NM_145109.3; = p.L225= on NM_002756.4) | Silent (SNP) | VAF 33/159 reads (21%) | catalogued as rs763941994, COSV100384148; called by muse, mutect2, varscan2
- MAPRE2 | c.105C>G p.R35= | Silent (SNP) | VAF 36/113 reads (32%) | called by muse, mutect2, varscan2
- MCM3AP | c.2907G>A p.G969= | Silent (SNP) | VAF 22/446 reads (5%) | called by muse, mutect2
- MIGA1 | c.972G>T p.T324= | Silent (SNP) | VAF 44/164 reads (27%) | catalogued as rs778601298; called by muse, mutect2, varscan2
- MKI67 | c.1161T>C p.D387= | Silent (SNP) | VAF 130/257 reads (51%) | called by muse, mutect2, varscan2
- MRTFA | c.870C>T p.P290= | Silent (SNP) | VAF 9/159 reads (6%) | called by muse, mutect2
- MUC16 | c.28947T>A p.S9649= | Silent (SNP) | VAF 85/162 reads (52%) | called by muse, mutect2, varscan2
- MYCBP2 | c.7308G>A p.K2436= (on ENST00000357337; = p.K2474= on NM_015057.5) | Silent (SNP) | VAF 26/88 reads (30%) | catalogued as rs1300829455, COSV62012495; called by muse, mutect2, varscan2
- MYH1 | c.2967G>A p.L989= | Silent (SNP) | VAF 228/393 reads (58%) | catalogued as COSV56845069, COSV99874705; called by muse, mutect2, varscan2
- MYO6 | c.2730C>T p.L910= | Silent (SNP) | VAF 11/205 reads (5%) | catalogued as COSV100889384; called by muse, mutect2
- NEK3 | c.150G>A p.E50= | Silent (SNP) | VAF 8/49 reads (16%) | called by muse, mutect2
- NEUROD6 | c.552C>T p.N184= | Silent (SNP) | VAF 79/224 reads (35%) | catalogued as rs967547086, COSV51771421; called by muse, mutect2, varscan2
- NOL11 | c.291G>A p.L97= | Silent (SNP) | VAF 41/70 reads (59%) | called by muse, mutect2, varscan2
- NOL4 | c.1644T>C p.N548= | Silent (SNP) | VAF 106/284 reads (37%) | called by muse, mutect2, varscan2
- NOP2 | c.1488G>C p.L496= (on ENST00000322166 / NM_001258308.2; = p.L492= on NM_006170.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 36/95 reads (38%) | catalogued as COSV59110153, COSV59111892; called by muse, mutect2, varscan2
- OBSL1 | c.4704G>A p.V1568= | Silent (SNP) | VAF 15/31 reads (48%) | catalogued as COSV54707598; called by muse, mutect2, varscan2
- OLFM2 | c.721C>A p.R241= | Silent (SNP) | VAF 8/50 reads (16%) | called by muse, mutect2, varscan2
- OR6C75 | c.201G>T p.L67= | Silent (SNP) | VAF 119/367 reads (32%) | called by muse, mutect2, varscan2
- PBX4 | c.642G>T p.R214= | Silent (SNP) | VAF 114/371 reads (31%) | called by muse, mutect2, varscan2
- PCLO | c.7731A>G p.T2577= | Silent (SNP) | VAF 124/221 reads (56%) | called by muse, mutect2, varscan2
- PDCD1 | c.810C>A p.G270= | Silent (SNP) | VAF 24/65 reads (37%) | called by muse, mutect2, varscan2
- PDGFB | c.495T>C p.F165= | Silent (SNP) | VAF 43/137 reads (31%) | called by muse, mutect2, varscan2
- PECR | c.522A>T p.A174= | Silent (SNP) | VAF 39/78 reads (50%) | catalogued as rs768006106; called by muse, mutect2, varscan2
- PLXNA1 | c.4191G>T p.L1397= | Silent (SNP) | VAF 23/62 reads (37%) | called by muse, mutect2, varscan2
- POU6F2 | c.384G>C p.A128= | Silent (SNP) | VAF 84/299 reads (28%) | catalogued as rs1283569251, COSV68874521; called by muse, mutect2, varscan2
- PRDX2 | c.198C>T p.R66= | Silent (SNP) | VAF 26/70 reads (37%) | called by muse, mutect2, varscan2
- PREX1 | c.2640C>T p.F880= | Silent (SNP) | VAF 18/106 reads (17%) | catalogued as rs373448744; called by muse, mutect2, varscan2
- RFX6 | c.1153C>A p.R385= | Silent (SNP) | VAF 47/162 reads (29%) | catalogued as CM166833, COSV60587707; called by muse, mutect2, varscan2
- RHOBTB2 | c.2148C>G p.S716= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as rs1460494102; called by muse, mutect2, varscan2
- RSU1 | c.567G>T p.G189= | Silent (SNP) | VAF 104/208 reads (50%) | called by muse, mutect2, varscan2
- SAMD4A | c.2028G>A p.L676= | Silent (SNP) | VAF 113/337 reads (34%) | called by muse, mutect2, varscan2
- SBDS | c.717G>C p.L239= | Silent (SNP) | VAF 68/207 reads (33%) | catalogued as COSV55887474; called by muse, mutect2, varscan2
- SERPINB5 | c.384G>A p.T128= | Silent (SNP) | VAF 45/124 reads (36%) | catalogued as rs757336116, COSV66975161; called by muse, mutect2, varscan2
- SIGLEC1 | c.1782G>T p.V594= | Silent (SNP) | VAF 18/29 reads (62%) | called by muse, mutect2, varscan2
- SIPA1L3 | c.504C>T p.H168= | Silent (SNP) | VAF 53/139 reads (38%) | called by muse, mutect2, varscan2
- SIPA1L3 | c.1680G>T p.R560= | Silent (SNP) | VAF 54/201 reads (27%) | called by muse, mutect2, varscan2
- SLC2A2 | c.1032A>T p.G344= | Silent (SNP) | VAF 25/176 reads (14%) | called by muse, mutect2, varscan2
- SLC35B2 | c.675G>A p.L225= | Silent (SNP) | VAF 55/201 reads (27%) | called by muse, mutect2, varscan2
- SMAP1 | c.981A>T p.T327= (on ENST00000370455 / NM_001044305.3; = p.T300= on NM_021940.5) | Silent (SNP) | VAF 70/204 reads (34%) | called by muse, mutect2, varscan2
- SMG8 | c.2196G>A p.K732= | Silent (SNP) | VAF 15/289 reads (5%) | catalogued as COSV99958941; called by muse, mutect2
- SON | c.147A>C p.A49= | Silent (SNP) | VAF 42/129 reads (33%) | called by muse, mutect2, varscan2
- SPA17 | c.123C>G p.A41= | Silent (SNP) | VAF 54/171 reads (32%) | called by muse, mutect2, varscan2
- SYT6 | c.333C>T p.F111= (on ENST00000610222 / NM_001366225.1; = p.F26= on NM_205848.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 150/401 reads (37%) | called by muse, mutect2, varscan2
- TMEM202 | c.459G>T p.L153= | Silent (SNP) | VAF 64/348 reads (18%) | called by muse, mutect2, varscan2
- TMEM63C | c.1407G>A p.L469= | Silent (SNP) | VAF 82/300 reads (27%) | called by muse, mutect2, varscan2
- TRAV16 | c.225C>T p.I75= | Silent (SNP) | VAF 19/59 reads (32%) | called by muse, mutect2, varscan2
- TTK | c.1530A>G p.A510= | Silent (SNP) | VAF 26/88 reads (30%) | catalogued as COSV100036428; called by muse, mutect2, varscan2
- TUBB6 | c.225C>T p.S75= | Silent (SNP) | VAF 27/106 reads (25%) | catalogued as rs1267098226, COSV58354476; called by muse, mutect2, varscan2
- UBN1 | c.2964G>A p.L988= | Silent (SNP) | VAF 30/226 reads (13%) | called by muse, mutect2, varscan2
- USH2A | c.2670C>A p.T890= | Silent (SNP) | VAF 127/222 reads (57%) | catalogued as rs1164198981, COSV100238639; called by muse, mutect2, varscan2
- USHBP1 | c.1425C>A p.P475= | Silent (SNP) | VAF 78/224 reads (35%) | called by muse, mutect2, varscan2
- VPS54 | c.1131A>G p.L377= | Silent (SNP) | VAF 16/69 reads (23%) | called by muse, mutect2, varscan2
- WDR49 | c.201C>T p.A67= (on ENST00000308378 / NM_001366158.1; = p.A408= on NM_001348951.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 42/341 reads (12%) | catalogued as rs370189335; called by muse, mutect2, varscan2
- ZNF205 | c.432G>T p.T144= | Silent (SNP) | VAF 37/105 reads (35%) | called by muse, mutect2, varscan2
- ZNF566 | c.354C>T p.F118= | Silent (SNP) | VAF 28/522 reads (5%) | catalogued as COSV101091485; called by muse, mutect2
- AL133467.6 | chr14:95668245 G>C | 5'Flank (SNP) | VAF 56/182 reads (31%) | called by muse, varscan2
- AL133467.6 | chr14:95668319 G>T | 5'Flank (SNP) | VAF 44/139 reads (32%) | called by muse, varscan2
- CD300LD | chr17:74592656 G>A | 5'Flank (SNP) | VAF 83/183 reads (45%) | called by muse, mutect2, varscan2
- FAM74A3 | n.53G>A | RNA (SNP) | VAF 11/25 reads (44%) | called by muse, mutect2, varscan2
- FBXL21P | n.988A>T | RNA (SNP) | VAF 86/175 reads (49%) | catalogued as COSV99778374; called by muse, mutect2, varscan2
- IGKV1-13 | n.316T>C | RNA (SNP) | VAF 82/468 reads (18%) | called by muse, mutect2, varscan2
- MIR18A | n.2G>C | RNA (SNP) | VAF 90/306 reads (29%) | called by muse, mutect2, varscan2
- MIR9-1HG | n.409C>G | RNA (SNP) | VAF 8/32 reads (25%) | called by muse, mutect2, varscan2
- PCDHA9 | c.2394+11C>G | Intron (SNP) | VAF 48/78 reads (62%) | called by muse, mutect2, varscan2
- PTBP3 | chr9:112220221 G>A | 3'Flank (SNP) | VAF 8/24 reads (33%) | catalogued as rs1268662556, COSV100534377; called by muse, mutect2, varscan2
- SLC26A7 | c.1935+188A>T | Intron (SNP) | VAF 30/102 reads (29%) | called by muse, mutect2, varscan2
- SNORD114-29 | n.13G>A | RNA (SNP) | VAF 19/183 reads (10%) | called by muse, mutect2, varscan2
- XIST | n.8731G>T | RNA (SNP) | VAF 35/50 reads (70%) | called by muse, mutect2, varscan2
